Somatic mutation profile of tumor specimen 0DV152 from CCDI case PBCJMP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Aggressive fibromatosis; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 1.1 years (409 days).
Specimen 0DV152: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74944105-00b4-4fd3-adc5-afceae205061.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV14H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4a810c1-3748-4c0f-8993-59bd0964446d

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.42688C>G p.Q14230E (on ENST00000591111; = p.Q6806E on NM_003319.4) | Missense Mutation (SNP) | VAF 167/438 reads (38%) | PolyPhen probably damaging (0.979); catalogued as rs1032020627, COSV60066480; called by muse, varscan2
- TTN | c.35116C>T p.P11706S (on ENST00000591111; = p.P10779S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/229 reads (26%) | PolyPhen benign (0.23); catalogued as rs766710373; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 44/962 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 49/834 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- TTN | c.42581C>T p.A14194V (on ENST00000591111; = p.A6770V on NM_003319.4) | Missense Mutation (SNP) | VAF 204/584 reads (35%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.45312C>T p.A15104= (on ENST00000591111; = p.A7680= on NM_003319.4) | Silent (SNP) | VAF 220/541 reads (41%) | called by muse, mutect2, varscan2
- C1orf146 | c.-32C>T | 5'UTR (SNP) | VAF 99/278 reads (36%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/35 reads (17%) | called by mutect2, varscan2
